Surgical pathology report (de-identified scan), TCGA case TCGA-24-1843, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1843-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

DIAGNOSIS:

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY (INCLUDING FS1A)

- HIGH GRADE SEROUS ADENOCARCINOMA
- SURFACE INVOLVEMENT BY ADENOCARCINOMA IS PRESENT
- LYMPHVASCULAR SPACE INVASION IDENTIFIED
- SEE SYNOPSIS

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA IN THE PERITUBAL SOFT TISSUE WITH EXTENSION INTO THE FALLOPIAN TUBE

SOFT TISSUE, PELVIC SIDEWALL, BIOPSY (FS1B)

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

SOFT TISSUE, BLADDER PERITONEUM, EXCISION

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

SOFT TISSUE, LEFT PELVIC SIDEWALL, EXCISION

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA, PRESENT WITHIN PERIOVARIAN SOFT TISSUE AND OVARIAN PARENCHYMA

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA PRESENT IN PERITUBAL SOFT TISSUE

SMALL INTESTINE, "SMALL BOWEL TUMOR," PARTIAL EXCISION

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA WITH INVASION INTO THE MUSCULARIS PROPRIA AND SUBMUCOSA WITH NECROSIS OF THE OVERLYING MUCOSA
- SURGICAL MARGINS FREE OF CARCINOMA
- SEROSAL ADHESIONS

APPENDIX, APPENDECTOMY

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA INVOLVING THE SEROSA AND COMPLETELY REPLACING THE LUMEN

SOFT TISSUE, "SMALL BOWEL NODULE," EXCISION

[page 2 of 4]
- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

SOFT TISSUE, "CECAL NODULE," EXCISION

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

SOFT TISSUE, "LARGE BOWEL TUMOR," EXCISION

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

SOFT TISSUE, OMENTUM, EXCISION

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

SOFT TISSUE, "COLON NODULE," EXCISION

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

SOFT TISSUE, "ANTERIOR ABDOMINAL WALL MASS," EXCISION

- PERSISTENT URACHUS WITH MARKED ACUTE AND CHRONIC INFLAMMATION

- CARCINOMA NOT IDENTIFIED

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides(and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

An intraoperative non microscopic consultation was obtained and interpreted as: "Brought to frozen 'right tube and ovary, pelvic sidewall' consisting of a 77-gram, 7 x 4.5 x 3.2 cm ovary and fallopian tube. The ovary is replaced by a 7 cm tan-white mass with tumor on the surface. The fallopian tube is draped over the ovarian mass and appears normal. Sections of the ovary show a solid lobulated mass. A portion is frozen as FS1A (surface inked for orientation). Also in the container is an irregular 2.8 x 2 x 1.5 cm tan-white mass. A portion is frozen as FS1B. A portion of the ovarian mass and normal fallopian tube is taken for [REDACTED]. Rest for permanents." [REDACTED]

FS1A: Ovary, right, biopsy

- "Poorly differentiated carcinoma consistent with Mullerian origin" by [REDACTED]

FS1B: Soft tissue, pelvic sidewall, biopsy

- "Poorly differentiated carcinoma consistent with Mullerian origin" by [REDACTED]

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is [REDACTED] with an ovarian tumor and a CA125 of 223. Operative procedure: Total abdominal hysterectomy and bilateral salpingo-oophorectomy.

Specimen(s) Received:

A: ANTERIOR ABDOMEN WALL MASS

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

B: RIGHT TUBE AND OVARY AND PELVIC SIDE WALL
C: BLADDER PERITONEUM
D: LEFT PELVIC SIDE WALL
E: LEFT TUBE AND OVARY
F: SMALL BOWEL TUMOR
G: APPENDIX
H: SMALL BOWEL NODULE
I: CECAL NODULE
J: LARGE BOWEL TUMOR
K: OMENTUM
L: COLON TUMOR

Gross Description:

The specimens are received in 12 formalin-filled containers, each labeled [REDACTED]. The first is additionally labeled "anterior abdominal wall mass." It holds a solid piece of tan-white, firm, fibrous tissue measuring 3 x 2 x 1.5 cm. Sectioned to show a yellow-brown solid cut surface with a central 0.2 cm cystic space. [REDACTED]

The second container is labeled "pelvic sidewall, right tube and ovary, FS1A/1B/X." It holds two white tissue cassettes. The first, labeled FS1A, holds a previously sectioned piece of tan tissue measuring 2 x 1 x 0.1 cm. Labeled B1 (FS1A). The second white tissue cassette, labeled FS1B, holds a previously sectioned piece of tan fibroadipose tissue measuring 2.2 x 0.5 x 0.1 cm. Labeled B2 (FS1B). Also in the container is a previously sectioned right fallopian tube and ovary specimen as described above the intraoperative consultation. The specimen measures 7 x 4.5 x 3.2 cm and has a focal area of black ink designating tumor on the ovarian surface. The cut surface is solid with a vaguely lobular pattern separated by fibrous bands. The 5 x 0.5 cm fallopian tube is diffusely adhered to the ovary and, on cut surface, has an unremarkable 0.1 cm lumen. Also in the container is a previously sampled piece of tan tissue designated as tumor from the pelvic sidewall measuring 1.5 x 1.5 x 0.3 cm. Labeled B3 and B4 - section of tumor in area of surface ink; B5 and B6 - additional sections of tumor; B7 - tumor in relationship to fallopian tube; B8 - remainder of pelvic side wall tumor. [REDACTED]

The third container is labeled "bladder peritoneum." It holds multiple fragments of firm tan-white tissue measuring 4.5 x 4.5 x 0.5 cm. Many of these fragments show firm white nodules consistent with involvement by metastatic tumor. [REDACTED]

The fourth container is labeled "left pelvic sidewall." It holds multiple pieces of tan firm tissue consistent with involvement by metastatic disease. These fragments measure 4 x 3 x 1.5 cm in aggregate. [REDACTED]

The fifth container is labeled "left tube and ovary." It holds a 21-gram left ovary and fallopian tube specimen. The ovary measures 3.5 x 1.5 x 0.5 cm. The periovarian and peritubal soft tissue is matted with a firm white nodule opposite the fallopian tube fimbria and measures 3 x 2 x 1.5 cm. The remainder of the 4.2 x 0.5 cm fallopian tube is unremarkable with the exception of multiple paratubal cysts. Labeled E1 - mass in relationship to fallopian tube; E2 - mass in relationship to ovary; E3 - ovary; E4 - additional sections of fallopian tube. [REDACTED]

The sixth container is labeled "small bowel tumor." It holds an unoriented piece of adhered small bowel measuring 15 cm in length with a uniform diameter of 2.5 cm. Centrally located is a serosal-based firm white mass measuring approximately 4 cm in greatest dimension causing extensive bowel adhesions. On sectioning, the mass has a solid white cut surface with focal areas of central degeneration and encroaches onto the bowel lumen with gross evidence of extension into the muscularis but not the mucosa. On opening, the small bowel mucosa has a normal folding pattern with no mucosal-based lesions or masses. Labeled F1 and F2 - margins; F3 to F5 - mass in relationship to bowel wall. [REDACTED]

The seventh container is labeled "appendix." It holds an 8.1 cm long appendix with attached mesoappendix measuring 1.5 cm in greatest depth. The appendiceal serosa is studded with multiple white nodules, the largest located 1.5 cm from the appendiceal tip and measures 1.2 cm in greatest dimension. The appendiceal diameter ranges from 0.6 cm in the uninvolved areas to 1.2 cm in the involved areas. No appendiceal perforations or serosal exudates are noted. Sectioned to show an obliterated appendiceal lumen. Multiple firm densities are present in the mesoappendix consistent with involvement by metastatic disease. [REDACTED]

The eighth container is labeled "small bowel nodule." It holds multiple tan-white nodules grossly consistent with the tumor seen at previous sites, measuring 2 x 1.5 x 0.3 cm. Wrapped. [REDACTED]

The ninth container is labeled "cecal nodule." It holds a single tan-white firm tissue fragment measuring 1.2 x 0.9 x 0.2 cm. [REDACTED]

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

The tenth container is labeled "large bowel tumor." It holds multiple pieces of fibroadipose tissue studded with firm white nodules grossly consistent with metastatic tumor. These tissue fragments measure 4 x 3.5 x 0.3 cm in aggregate.

The 11th container is labeled "omentum." It holds a single piece of fibroadipose tissue grossly consistent with omentum, measuring 15 x 12 x 2 cm. Multiple tumor deposits are present, the largest measuring 5.5 cm in greatest dimension. On cut surface, these tumor deposits are solid and white.

The 12th container is labeled "colon nodule." It holds multiple pieces of firm white tissue grossly consistent with tumor identified elsewhere. These fragments measure 2.5 x 2 x 0.3 cm in aggregate.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The location of the primary tumor is the right ovary only

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the extrapelvic peritoneum is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/NX/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 196c20e1-cd62-4364-9f3e-ff8a22b9a708 (TCGA-24-1843.D2625C77-0F03-42EA-B5EA-DF45769F0FBB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).